Somatic mutation profile of tumor specimen TARGET-30-PAVCJZ-01A (aliquot TARGET-30-PAVCJZ-01A-01D) from TARGET case TARGET-30-PAVCJZ, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 4.6 years (1,667 days).
Specimen TARGET-30-PAVCJZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48cc6ca3-90d4-455c-9185-d55770d7befb.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAVCJZ-10A (Blood Derived Normal), aliquot TARGET-30-PAVCJZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bdfb901c-dcba-4edb-96f5-6c1b2fc8aeed

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.1132G>T p.V378F | Missense Mutation (SNP) | VAF 34/301 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV59263129; called by muse, mutect2, varscan2
- ROR1 | c.155T>C p.L52P | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.077); called by muse, mutect2
- ROR1 | c.156C>T p.L52= | Silent (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
